Somatic mutation profile of tumor specimen 0DK1WD from CCDI case PBBXRW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 7.5 years (2,722 days).
Specimen 0DK1WD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5cc9f763-4645-43bd-9926-a4a36eb1e4c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DK1WJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b50e151-260d-4784-bc4c-a6bdd8b0b50b

The open-access MAF lists 9 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Missense Mutation 3, 3'UTR 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNTN2 | c.2111G>A p.R704Q | Missense Mutation (SNP) | VAF 26/640 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs139732381; called by muse, mutect2
- TUBGCP6 | c.4357C>T p.R1453W | Missense Mutation (SNP) | VAF 308/658 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as rs200744244; called by muse, mutect2, varscan2
- UBR4 | c.6850C>T p.Q2284* | Nonsense Mutation (SNP) | VAF 201/734 reads (27%) | called by muse, mutect2, varscan2
- VCAM1 | c.1537G>A p.D513N | Missense Mutation (SNP) | VAF 217/692 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL16A1 | c.408C>T p.N136= | Silent (SNP) | VAF 385/644 reads (60%) | catalogued as rs1473626975; called by muse, mutect2, varscan2
- PKNOX2 | c.243G>A p.P81= | Silent (SNP) | VAF 46/554 reads (8%) | catalogued as rs758344216, COSV53544311; called by muse, mutect2
- STK26 | c.984C>T p.T328= | Silent (SNP) | VAF 13/435 reads (3%) | catalogued as rs1401895033, COSV100048880, COSV53746303; called by muse, mutect2
- GRXCR2 | c.*41A>T | 3'UTR (SNP) | VAF 133/557 reads (24%) | called by muse, mutect2, varscan2
- MUC17 | c.*42C>T | 3'UTR (SNP) | VAF 105/287 reads (37%) | catalogued as rs373198651, COSV60290418; called by muse, mutect2, varscan2
